CCDI case PBBWVF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c0dc7358-cdfd-49c1-95e1-6f4de313269b

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.4 years (1,601 days).

Biospecimens (3 samples)
- Sample 0DJBLS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJC35: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJC3B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
